Somatic mutation profile of tumor specimen f0bb6ff4-7cb8-427f-84bf-7f51d7 (aliquot f0bb6ff4-7cb8-427f-84bf-7f51d7_D6_1) from CPTAC case 20CO004, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen f0bb6ff4-7cb8-427f-84bf-7f51d7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acadb589-512e-485b-b3cd-8965816f2387.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 21d715d5-1958-42d0-b14a-efb87f (Blood Derived Normal), aliquot 21d715d5-1958-42d0-b14a-efb87f_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f855d72-7685-4afc-a5af-8b83f38d189d

The open-access MAF lists 229 somatic variants for this specimen: 135 protein-altering or splice-affecting, 53 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 53, Intron 19, 5'UTR 13, Nonsense Mutation 8, Frame Shift Del 4, Frame Shift Ins 4, 3'UTR 4, RNA 3, Splice Region 3, Splice Site 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2701C>T p.Q901* | Nonsense Mutation (SNP) | VAF 137/353 reads (39%) | catalogued as rs1114167559, CM105838, COSV57381203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 82/250 reads (33%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- FLNC | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs1114167361, CM1513881, COSV57951027; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 103/297 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PROC | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 122/358 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757583846, CM950979, CM950980; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 105/275 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 55/107 reads (51%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAD10 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs755827248; called by muse, mutect2, varscan2
- ACOXL | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265915879; called by muse, mutect2, varscan2
- ACTA1 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 106/261 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as rs1369749149, COSV64203882; called by muse, mutect2, varscan2
- BRD8 | c.806G>A p.R269Q (on ENST00000254900 / NM_139199.2; = p.R342Q on NM_006696.4) | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs780590349; called by muse, mutect2, varscan2
- C1orf116 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 102/289 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV63943938; called by muse, mutect2, varscan2
- CACNB4 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as rs879034904; called by muse, mutect2, varscan2
- CAPN6 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1403846006, COSV60697534; called by muse, mutect2
- CASZ1 | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59734130; called by muse, mutect2, varscan2
- CCDC105 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52964641; called by muse, mutect2, varscan2
- CDC42BPA | c.1849T>G p.L617V | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as rs780676383; called by muse, mutect2, varscan2
- CFAP46 | c.8012C>T p.A2671V | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs199869831, COSV54148585; called by muse, mutect2, varscan2
- CHD4 | c.3490C>T p.R1164C (on ENST00000357008 / NM_001363606.2; = p.R1177C on NM_001273.5) | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV58899667; called by muse, mutect2, varscan2
- CLEC2L | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV70691624; called by muse, mutect2, varscan2
- CTNND2 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1398024593, COSV58866982; called by muse, mutect2, varscan2
- DMD | c.10712G>A p.R3571H | Missense Mutation (SNP) | VAF 131/175 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs935091512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH12 | c.8995G>A p.D2999N (on ENST00000351747; = p.D3867N on NM_001366028.2) | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs771415973; called by muse, mutect2, varscan2
- DOCK6 | c.4778C>T p.P1593L | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749873634; called by muse, mutect2, varscan2
- DSC3 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs774233423, COSV100844680, COSV64574247; called by muse, mutect2
- FABP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 93/257 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55559226; called by muse, mutect2, varscan2
- GLI2 | c.1748G>A p.R583H (on ENST00000361492 / NM_001374353.1; = p.R600H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/456 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762992052, COSV58053880; called by muse, mutect2, varscan2
- H2BC7 | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.163); catalogued as rs200684560; called by muse, mutect2
- HEATR1 | c.5653G>A p.D1885N | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs536014077, COSV100857721; called by muse, mutect2, varscan2
- IFNA17 | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 127/323 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs769441651; called by muse, mutect2, varscan2
- IGHM | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.205); catalogued as rs759494596; called by muse, mutect2, varscan2
- IRS2 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 247/349 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768235363; called by muse, mutect2, varscan2
- KIAA1755 | c.1928C>G p.P643R | Missense Mutation (SNP) | VAF 129/218 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99642421; called by muse, mutect2, varscan2
- L1CAM | c.3129C>A p.C1043* | Nonsense Mutation (SNP) | VAF 82/117 reads (70%) | catalogued as COSV100649134, COSV62829890; called by mutect2, varscan2
- MAGEB5 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 121/158 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1338426581; called by muse, mutect2, varscan2
- MAGEB6 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 109/149 reads (73%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.64); catalogued as rs775370255, COSV66872399; called by muse, mutect2, varscan2
- MCTP2 | c.2271G>T p.L757F | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.48); PolyPhen benign (0.199); catalogued as COSV63293555; called by muse, mutect2, varscan2
- MDGA2 | c.1780G>A p.V594M (on ENST00000399232 / NM_001113498.2; = p.V296M on NM_182830.4) | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs753607530, COSV62078530; called by muse, mutect2, varscan2
- MPZL2 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs748123306; called by muse, mutect2, varscan2
- MUC12 | c.5018C>T p.T1673M (on ENST00000379442; = p.T1530M on NM_001164462.1) | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.368); catalogued as rs376651770; called by mutect2, varscan2
- MYRF | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs750888932; called by muse, mutect2, varscan2
- OR51G2 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV58994271; called by muse, varscan2
- OTUD4 | c.1369C>T p.R457C (on ENST00000447906 / NM_001366057.1; = p.R392C on NM_001102653.1) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1251800770; called by muse, mutect2, varscan2
- PAN2 | c.3151G>A p.D1051N (on ENST00000425394 / NM_001127460.3; = p.D1047N on NM_014871.5) | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99228264; called by muse, mutect2, varscan2
- PCDH15 | c.4702G>A p.V1568I | Missense Mutation (SNP) | VAF 181/498 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs150023169, COSV64686242, COSV64702174; called by muse, mutect2, varscan2
- PCDHA12 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56479342; called by muse, mutect2, varscan2
- PCDHGA3 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs752621108; called by muse, mutect2, varscan2
- PCDHGA4 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 108/285 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs762398968, COSV53893624; called by muse, mutect2, varscan2
- PHACTR2 | c.685dup p.T229Nfs*5 | Frame Shift Ins (INS) | VAF 28/99 reads (28%) | catalogued as rs746858891; called by mutect2, varscan2
- PREX2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376775544; called by muse, mutect2, varscan2
- PSD | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs755558509, COSV99193037; called by muse, mutect2, varscan2
- RBFOX1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as rs544967209; called by muse, mutect2, varscan2
- RC3H2 | c.3226A>G p.I1076V | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT tolerated, low confidence (0.74); PolyPhen possibly damaging (0.456); catalogued as rs1429152381; called by muse, mutect2
- RDH10 | c.695A>G p.E232G | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs920379933; called by muse, mutect2, varscan2
- ROBO2 | c.3714C>A p.D1238E | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59902780; called by muse, mutect2
- RTN1 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs780650595, COSV50720798; called by muse, mutect2, varscan2
- SEC61A1 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as rs769682649; called by muse, mutect2, varscan2
- SEMA7A | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 78/121 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs150967406; called by muse, mutect2, varscan2
- SEPTIN2 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1434400019, COSV100764998; called by muse, mutect2, varscan2
- SLC2A3 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); catalogued as rs372816217; called by muse, mutect2, varscan2
- SLC8A1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765590704, COSV100244497; called by muse, mutect2, varscan2
- SPATA5 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 63/130 reads (48%) | catalogued as rs763737752, COSV56776042, COSV56780055; called by muse, mutect2, varscan2
- TECPR2 | c.3730C>T p.Q1244* | Nonsense Mutation (SNP) | VAF 59/166 reads (36%) | catalogued as rs1567353781; called by muse, mutect2, varscan2
- THSD7B | c.2310A>T p.Q770H | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99744796; called by muse, mutect2, varscan2
- TICAM1 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs762981932; called by muse, mutect2, varscan2
- TRPM2 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749957248, COSV55967986; called by muse, mutect2, varscan2
- TRUB1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772597952; called by muse, mutect2, varscan2
- TTC21A | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 188/488 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV57188889; called by muse, varscan2
- TTLL12 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as rs1278999520; called by muse, mutect2, varscan2
- TTN | c.52846C>G p.R17616G (on ENST00000591111; = p.R10192G on NM_003319.4) | Missense Mutation (SNP) | VAF 49/129 reads (38%) | PolyPhen probably damaging (0.998); catalogued as COSV60246744; called by muse, mutect2, varscan2
- ZNF287 | c.1988T>C p.L663P | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67689124; called by muse, mutect2
- ZNF385A | c.1046G>A p.R349H (on ENST00000338010 / NM_001130967.3; = p.R329H on NM_015481.3) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs760571183; called by muse, mutect2, varscan2
- ZNF804A | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866204252; called by muse, mutect2, varscan2
- ANK1 | c.2386G>A p.V796M | Missense Mutation (SNP) | VAF 106/187 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- ARFGEF3 | c.5752A>G p.M1918V | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2
- ARHGEF17 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP1B1 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 124/370 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V1B1 | c.745G>C p.G249R | Missense Mutation (SNP) | VAF 131/467 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BIRC6 | c.4301A>C p.D1434A | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- C21orf58 | c.445-1G>A p.X149_splice | Splice Site (SNP) | VAF 116/210 reads (55%) | called by muse, varscan2
- CARMIL1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CATSPERB | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CDH10 | c.1652A>G p.K551R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDHR5 | c.264G>A p.E88= | Splice Region (SNP) | VAF 124/321 reads (39%) | called by muse, mutect2, varscan2
- CHEK1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHIT1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 205/575 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL6A3 | c.2323T>G p.C775G | Missense Mutation (SNP) | VAF 191/615 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DENND2A | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- DISP3 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ELN | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 151/399 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ETV2 | c.829-5C>T | Splice Region (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- FBXO38 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- FGA | c.1954C>A p.L652I | Missense Mutation (SNP) | VAF 120/183 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- FGF18 | c.32+1G>A p.X11_splice | Splice Site (SNP) | VAF 73/187 reads (39%) | called by muse, mutect2, varscan2
- FPGT | c.569A>T p.E190V | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FZD10 | c.99A>T p.K33N | Missense Mutation (SNP) | VAF 114/304 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- GAR1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.14); called by muse, varscan2
- GCNT3 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 129/187 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GNAT3 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- GPX4 | c.224A>T p.K75M | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- HAS1 | c.805del p.I269Sfs*12 | Frame Shift Del (DEL) | VAF 100/349 reads (29%) | called by mutect2, pindel, varscan2
- HERC5 | c.1163T>A p.I388N | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.053); called by mutect2, varscan2
- IRAK3 | c.1319T>C p.L440S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ISM2 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 76/196 reads (39%) | called by muse, mutect2, varscan2
- KIAA0825 | c.2387A>T p.E796V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- KIR3DL2 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- LRCH1 | c.904_914del p.L302Gfs*17 | Frame Shift Del (DEL) | VAF 31/66 reads (47%) | called by mutect2, pindel, varscan2
- MAGI2 | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP16 | c.959dup p.N320Kfs*2 | Frame Shift Ins (INS) | VAF 78/361 reads (22%) | called by mutect2, pindel, varscan2
- NADSYN1 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- NEFH | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- OR8H1 | c.712T>G p.S238A | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PCDHB12 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 141/337 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCMTD2 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 54/453 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- PIGT | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.10292T>C p.V3431A | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- PREX1 | c.3427_3439del p.G1143Cfs*18 | Frame Shift Del (DEL) | VAF 71/531 reads (13%) | called by mutect2, pindel, varscan2
- PRPF38B | c.1221del p.D408Mfs*123 | Frame Shift Del (DEL) | VAF 53/144 reads (37%) | called by mutect2, pindel, varscan2
- PSME4 | c.4150G>C p.A1384P | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- RFPL4A | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- SCRN3 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SDC2 | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA5A | c.1064T>G p.F355C | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SKIL | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC26A5 | c.1514+3G>A | Splice Region (SNP) | VAF 140/354 reads (40%) | called by muse, varscan2
- SLC30A7 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 67/143 reads (47%) | called by muse, mutect2, varscan2
- SP140 | c.1352_1353insC p.E452* | Frame Shift Ins (INS) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- SYT9 | c.1280T>A p.V427D | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TBX15 | c.70A>C p.I24L | Missense Mutation (SNP) | VAF 170/430 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TEX14 | c.2393C>A p.S798Y (on ENST00000240361 / NM_001201457.2; = p.S792Y on NM_031272.5) | Missense Mutation (SNP) | VAF 116/214 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by mutect2, varscan2
- TIAM2 | c.3863G>T p.S1288I | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TYRP1 | c.1060A>T p.S354C | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIC1 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF804B | c.308A>C p.K103T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC069544.2 | c.1036C>T p.L346= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV65685088; called by muse, mutect2, varscan2
- ACTR5 | c.324T>G p.L108= | Silent (SNP) | VAF 41/170 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.4848C>T p.T1616= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs145474293; called by muse, mutect2, varscan2
- ADAT3 | c.1095C>T p.P365= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs370276587; called by muse, mutect2, varscan2
- AL136295.1 | c.1797G>A p.T599= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs775780012; called by muse, mutect2, varscan2
- ATE1 | c.45C>T p.F15= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs1276361779; called by muse, mutect2
- CCDC171 | c.2913G>A p.S971= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs375214888, COSV99899995; called by muse, varscan2
- CCDC27 | c.285G>A p.S95= | Silent (SNP) | VAF 82/195 reads (42%) | catalogued as rs145525732; called by muse, mutect2, varscan2
- CCN5 | c.609C>G p.P203= | Silent (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- CHMP1A | c.159C>A p.I53= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV99498441; called by muse, mutect2, varscan2
- CLDN11 | c.534C>T p.C178= | Silent (SNP) | VAF 140/416 reads (34%) | catalogued as rs780400487, COSV50355180; called by mutect2, varscan2
- CNTNAP3 | c.3510G>A p.A1170= | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as rs1312361811; called by muse, mutect2, varscan2
- COL27A1 | c.4926A>T p.A1642= | Silent (SNP) | VAF 44/117 reads (38%) | called by muse, mutect2, varscan2
- COL6A6 | c.3123G>A p.A1041= | Silent (SNP) | VAF 112/279 reads (40%) | catalogued as rs765035822; called by muse, mutect2, varscan2
- EEPD1 | c.1662C>T p.S554= | Silent (SNP) | VAF 76/201 reads (38%) | catalogued as rs573490745, COSV54200586; called by muse, mutect2, varscan2
- EXOSC3 | c.78G>A p.Q26= | Silent (SNP) | VAF 73/195 reads (37%) | called by muse, mutect2, varscan2
- FAM107B | c.372C>T p.H124= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs1162171830, COSV51687505; called by muse, mutect2, varscan2
- FAM205A | c.237C>A p.L79= | Silent (SNP) | VAF 62/181 reads (34%) | called by muse, mutect2
- FOXL2NB | c.360C>T p.A120= | Silent (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- GAMT | c.651G>A p.P217= | Silent (SNP) | VAF 127/342 reads (37%) | catalogued as rs745327521; called by muse, mutect2, varscan2
- H2BC10 | c.330C>T p.H110= | Silent (SNP) | VAF 62/163 reads (38%) | called by muse, mutect2, varscan2
- ITPR1 | c.2592G>A p.T864= (on ENST00000354582; = p.T849= on NM_002222.7) | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs769157001; called by muse, mutect2, varscan2
- JADE2 | c.354G>A p.P118= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as rs776817859, COSV50919859; called by muse, mutect2, varscan2
- KCNB1 | c.1366C>A p.R456= | Silent (SNP) | VAF 78/372 reads (21%) | catalogued as rs368043123, COSV65568219; called by muse, mutect2, varscan2
- KIAA1549L | c.5289C>T p.I1763= (on ENST00000321505; = p.I2060= on NM_012194.3) | Silent (SNP) | VAF 92/206 reads (45%) | catalogued as rs374963931, COSV100382674; called by muse, mutect2, varscan2
- KLHL29 | c.1788G>T p.G596= | Silent (SNP) | VAF 55/138 reads (40%) | called by muse, mutect2, varscan2
- LPGAT1 | c.42C>G p.L14= | Silent (SNP) | VAF 66/198 reads (33%) | called by muse, mutect2, varscan2
- LURAP1 | c.609G>A p.G203= | Silent (SNP) | VAF 76/185 reads (41%) | called by muse, mutect2, varscan2
- MMS22L | c.1731C>T p.F577= | Silent (SNP) | VAF 80/246 reads (33%) | called by muse, mutect2, varscan2
- MORC2 | c.2970G>A p.T990= (on ENST00000397641 / NM_001303256.3; = p.T928= on NM_014941.3) | Silent (SNP) | VAF 125/307 reads (41%) | catalogued as rs781327828, COSV53203448; ClinVar: likely benign; called by muse, mutect2, varscan2
- MSH4 | c.2262G>A p.S754= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs535396708; called by muse, mutect2, varscan2
- MTDH | c.1179T>C p.D393= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs1472218396; called by muse, mutect2, varscan2
- MUC16 | c.1884C>A p.T628= | Silent (SNP) | VAF 124/350 reads (35%) | called by muse, mutect2, varscan2
- NEB | c.4917A>G p.K1639= | Silent (SNP) | VAF 10/211 reads (5%) | called by muse, mutect2
- OR5V1 | c.426T>C p.N142= | Silent (SNP) | VAF 71/227 reads (31%) | called by muse, mutect2, varscan2
- PAPLN | c.24G>A p.P8= | Silent (SNP) | VAF 66/164 reads (40%) | called by muse, mutect2, varscan2
- PDE12 | c.1215C>T p.L405= | Silent (SNP) | VAF 87/252 reads (35%) | catalogued as rs1231152854; called by muse, mutect2, varscan2
- RHO | c.804C>T p.Y268= | Silent (SNP) | VAF 242/624 reads (39%) | catalogued as rs200826498; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNF168 | c.69C>T p.L23= | Silent (SNP) | VAF 63/187 reads (34%) | called by muse, mutect2, varscan2
- SCN11A | c.855G>A p.S285= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as rs1466104684; called by muse, mutect2, varscan2
- SLFN5 | c.2625T>C p.C875= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs778409855; called by muse, mutect2, varscan2
- SNRNP27 | c.60C>T p.S20= | Silent (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- SYT3 | c.1569C>T p.Y523= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as rs762554717, COSV58895854; called by muse, mutect2
- TCF7L1 | c.567T>C p.H189= | Silent (SNP) | VAF 84/182 reads (46%) | catalogued as rs778823137; called by muse, mutect2, varscan2
- TF | c.1680C>T p.N560= | Silent (SNP) | VAF 97/258 reads (38%) | called by muse, mutect2, varscan2
- TRHDE | c.1032T>C p.T344= | Silent (SNP) | VAF 66/156 reads (42%) | called by muse, mutect2, varscan2
- TTC6 | c.3339T>C p.I1113= | Silent (SNP) | VAF 64/168 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.3060G>A p.E1020= (on ENST00000591111; = p.E974= on NM_003319.4) | Silent (SNP) | VAF 11/262 reads (4%) | called by muse, mutect2
- TUT1 | c.2367C>T p.T789= | Silent (SNP) | VAF 124/345 reads (36%) | called by muse, mutect2, varscan2
- WSB2 | c.57C>T p.H19= | Silent (SNP) | VAF 58/164 reads (35%) | called by muse, varscan2
- ZDHHC7 | c.309C>T p.T103= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as rs758168383, COSV58213587; called by muse, mutect2, varscan2
- ZNF589 | c.798C>T p.H266= | Silent (SNP) | VAF 96/240 reads (40%) | catalogued as rs777981813; called by muse, varscan2
- ZNF749 | c.1059T>C p.R353= | Silent (SNP) | VAF 69/232 reads (30%) | called by muse, mutect2, varscan2
- ACAD8 | c.1093-29C>A | Intron (SNP) | VAF 97/286 reads (34%) | called by muse, mutect2, varscan2
- AL355390.1 | n.692G>T | RNA (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- ALX4 | c.-12C>T | 5'UTR (SNP) | VAF 65/160 reads (41%) | catalogued as COSV61326301; called by muse, mutect2, varscan2
- ANKRD17 | c.393+35285C>G | Intron (SNP) | VAF 31/88 reads (35%) | catalogued as rs752495366; called by muse, mutect2, varscan2
- APBB1 | c.722-978C>T | Intron (SNP) | VAF 107/277 reads (39%) | catalogued as rs1470877847; called by muse, mutect2, varscan2
- AZIN2 | c.1029+3660A>C | Intron (SNP) | VAF 45/123 reads (37%) | called by muse, mutect2, varscan2
- BATF2 | c.142-247C>T | Intron (SNP) | VAF 93/207 reads (45%) | catalogued as rs1022082400, COSV100101792; called by muse, mutect2, varscan2
- BRCA1 | c.-20+90G>A | Intron (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- C12orf43 | c.145+47C>T | Intron (SNP) | VAF 114/282 reads (40%) | called by muse, mutect2, varscan2
- CHORDC1 | c.64+41C>T | Intron (SNP) | VAF 46/123 reads (37%) | catalogued as rs751604444; called by muse, mutect2, varscan2
- CLRN1 | c.*136G>A | 3'UTR (SNP) | VAF 83/228 reads (36%) | catalogued as rs768481587; called by muse, mutect2, varscan2
- CPT2 | c.-98G>A | 5'UTR (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- DBI | c.-22G>A | 5'UTR (SNP) | VAF 46/139 reads (33%) | catalogued as COSV100275833; called by muse, mutect2, varscan2
- DHX57 | c.1905+16T>G | Intron (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- DNAH8 | c.-155G>A | 5'UTR (SNP) | VAF 26/76 reads (34%) | catalogued as COSV59483673; called by muse, mutect2, varscan2
- DNAJC19 | c.*508C>T | 3'UTR (SNP) | VAF 180/420 reads (43%) | catalogued as rs1353055614; called by muse, varscan2
- DPH2 | c.260+56del | Intron (DEL) | VAF 94/318 reads (30%) | catalogued as COSV52544229; called by mutect2, pindel, varscan2
- ELL3 | c.-28C>A | 5'UTR (SNP) | VAF 50/79 reads (63%) | catalogued as rs375784280; called by mutect2, varscan2
- GSTM4 | c.-60G>A | 5'UTR (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1017G>T | RNA (SNP) | VAF 110/202 reads (54%) | called by muse, mutect2, varscan2
- LYRM7 | c.-30C>T | 5'UTR (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- MIR371A | n.51C>A | RNA (SNP) | VAF 80/204 reads (39%) | called by muse, mutect2, varscan2
- MIRLET7BHG | n.309-3445G>C | Intron (SNP) | VAF 53/136 reads (39%) | called by muse, mutect2, varscan2
- MYO5C | c.-26C>T | 5'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2
- NR1H4 | c.-13G>A | 5'UTR (SNP) | VAF 37/91 reads (41%) | catalogued as rs1209681221, COSV99500641; called by muse, mutect2, varscan2
- PDCD6 | c.-58C>T | 5'UTR (SNP) | VAF 39/93 reads (42%) | catalogued as rs1190770970; called by muse, mutect2, varscan2
- PIH1D1 | c.91-30C>T | Intron (SNP) | VAF 30/80 reads (38%) | catalogued as rs375991595; called by mutect2, varscan2
- PLD5 | c.189+74693C>A | Intron (SNP) | VAF 34/100 reads (34%) | catalogued as rs1164632537; called by muse, mutect2, varscan2
- RBM3 | chrX:48574846 C>T | 5'Flank (SNP) | VAF 37/46 reads (80%) | catalogued as rs1556988841; called by muse, mutect2, varscan2
- RGMB | c.-20C>T | 5'UTR (SNP) | VAF 22/36 reads (61%) | catalogued as rs866434735, COSV100375060; called by muse, varscan2
- RNF222 | c.*4G>A | 3'UTR (SNP) | VAF 44/74 reads (59%) | called by muse, mutect2, varscan2
- SLC2A4 | c.33+459C>T | Intron (SNP) | VAF 62/106 reads (58%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.-97+468G>T | Intron (SNP) | VAF 90/355 reads (25%) | called by muse, mutect2, varscan2
- SMARCB1 | c.*245T>G | 3'UTR (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- STT3B | c.-13G>A | 5'UTR (SNP) | VAF 12/43 reads (28%) | catalogued as rs372021397; called by muse, mutect2, varscan2
- SWAP70 | c.643-1136G>A | Intron (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- SYT7 | c.215+5176C>T | Intron (SNP) | VAF 38/71 reads (54%) | catalogued as rs962295988; called by muse, mutect2, varscan2
- TSHR | c.318-26G>T | Intron (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- TTLL7 | c.-368C>T | 5'UTR (SNP) | VAF 69/181 reads (38%) | catalogued as rs373559053; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23223G>A | Intron (SNP) | VAF 109/288 reads (38%) | called by muse, mutect2, varscan2
- ZNF503 | chr10:75403285 G>A | 5'Flank (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
